Somatic mutation profile of tumor specimen MP2PRT-PAULRX-TMP1-A (aliquot MP2PRT-PAULRX-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAULRX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (935 days).
Specimen MP2PRT-PAULRX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45188090-2085-4852-b866-4e3e5687eb8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULRX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULRX-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a11b72b-fed3-4580-a102-2c25f2fa2d67

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Splice Site 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG7 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.816); catalogued as rs140959989; called by muse, mutect2, varscan2
- DSP | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 123/345 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs727505037, COSV65791851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.9835G>A p.A3279T | Missense Mutation (SNP) | VAF 193/415 reads (47%) | SIFT tolerated (0.96); PolyPhen benign (0.037); catalogued as rs115482787, COSV64246012; called by muse, mutect2, varscan2
- FREM2 | c.3234G>A p.M1078I | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1163258639; called by muse, mutect2, varscan2
- HSPA8 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 24/369 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV99914624; called by muse, mutect2
- IGKV1-16 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs953468868; called by muse, varscan2
- NFATC1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 184/515 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.656); catalogued as rs751291857; called by muse, mutect2, varscan2
- NRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV65746912; called by muse, mutect2
- NXF5 | n.1058+1G>T | Splice Site (SNP) | VAF 109/328 reads (33%) | catalogued as COSV53793213; called by muse, mutect2, varscan2
- SACS | c.10907G>A p.R3636Q | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs281865119, CM107277, COSV66537296; ClinVar: uncertain significance; called by muse, mutect2
- DHX15 | c.460C>G p.Q154E | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2
- EMC2 | c.306-1G>T p.X102_splice | Splice Site (SNP) | VAF 3/14 reads (21%) | called by muse, varscan2
- ETV6 | c.206_207insA p.W69* | Nonsense Mutation (INS) | VAF 196/524 reads (37%) | called by mutect2, pindel, varscan2
- FCSK | c.2330G>A p.C777Y | Missense Mutation (SNP) | VAF 149/503 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC19A2 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- AMER1 | c.2448G>C p.R816= | Silent (SNP) | VAF 158/472 reads (33%) | called by muse, mutect2, varscan2
- ATP10D | c.3345C>G p.L1115= | Silent (SNP) | VAF 14/253 reads (6%) | called by muse, mutect2
- BICRA | c.2250C>T p.P750= | Silent (SNP) | VAF 172/448 reads (38%) | catalogued as rs1160326045, COSV101194466; called by mutect2, varscan2
- CYSLTR1 | c.636C>T p.I212= | Silent (SNP) | VAF 21/225 reads (9%) | called by muse, mutect2
- MLIP | c.333C>T p.F111= | Silent (SNP) | VAF 191/449 reads (43%) | catalogued as rs201706379; called by muse, mutect2, varscan2
- NLE1 | c.270C>A p.I90= | Silent (SNP) | VAF 103/364 reads (28%) | called by muse, mutect2, varscan2
- PROC | c.1233C>T p.H411= | Silent (SNP) | VAF 47/551 reads (9%) | catalogued as rs777430545, COSV52165231; called by muse, mutect2
- WNK1 | c.1191G>A p.E397= | Silent (SNP) | VAF 13/350 reads (4%) | catalogued as COSV60034238, COSV60043232; called by muse, mutect2
- DEPDC5 | c.*484G>A | 3'UTR (SNP) | VAF 81/269 reads (30%) | catalogued as COSV56697176, COSV56698857; called by muse, mutect2, varscan2
